Gene-level copy-number profile of tumor specimen HCM-CSHL-0059-C25-01A from HCMI case HCM-CSHL-0059-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 80.1 years (29,271 days).
Specimen HCM-CSHL-0059-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8ff8465a-0861-44ec-a1d6-4605c08ab67b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0059-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/a95306b9-f1ed-417e-b9c9-e24c78cc8879

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 875; copy number 1: 6,071; copy number 2: 44,271; copy number 3: 6,188; copy number 4: 76; copy number 5: 626; copy number 6: 44; copy number 9: 128; copy number 11: 7; copy number 13: 29; copy number 14: 50; copy number 15: 17; copy number 18: 19; copy number 19: 1.

Homozygous deletions (total copy number 0; autosomes only): 875 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,409,560–30,844,110, 10 genes: AL161638.2, AL161638.1, MATN1, MATN1-AS1, AL137857.1, LAPTM5, MIR4420, AL137027.1, LINC01778, RN7SKP91.
- chr12:1,970,786–6,124,770, 91 genes (within-gene range 0–1) (broad region; genes not listed).
- chr15:47,133,495–48,963,919, 35 genes: AC066615.1, SEMA6D, RN7SKP139, AC084882.1, AC023905.1, AC009558.1, AC009558.2, AC012050.1, AC044787.1, LINC01491, AC092078.2, AC092078.1, AC092078.3, SLC24A5, MYEF2, CTXN2, SLC12A1, AC066612.1, AC066612.2, AC023355.1, Y_RNA, DUT, FBN1, AC022467.2, AC022467.1, AC084757.3, AC084757.4, CEP152, AC084757.1, AC084757.2, AC012379.1, AC012379.2, SHC4, EID1, AC091073.1.
- chr18:25,061,924–80,247,514, 739 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 921 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:164,171,471–198,123,232, 623 genes, copy number 5 (broad region; genes not listed).
- chr8:31,639,222–43,030,535, 202 genes, copy number 6–18 (within-gene range 4–18) (broad region; genes not listed).
- chr11:48,880,111–48,902,181, 3 genes, copy number 5: AC027369.6, AC027369.3, AC027369.4.
- chr18:20,946,906–25,056,760, 93 genes, copy number 6–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,071. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
